Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A3KU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A3KU-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3
carcinoma, serous, NOS 8441/3
Site: endometrium C54.1 WJ
12/21/11

Surgical Pathology Consultation Report

Copy To:

Specimen(s) Received

1. Lymph node: Right Periaortic .
2. Left peri-aortic lymph node
3. Right external iliac lymph node
4. Right obturator
5. Left external iliac nodes
6. Left obturator
7. Omentum
8. Uterus, cervix, bilateral tubes and ovaries

Diagnosis

1. Lymph node (right periaortic), biopsy:
- Seven lymph nodes, negative for metastatic carcinoma (0/7)
2. Lymph node (left periaortic), biopsy:
- Two lymph nodes, negative for metastatic carcinoma (0/2)
3. Lymph node (right external iliac), biopsy:
- Three lymph nodes, negative for metastatic carcinoma (0/3)
4. Lymph node (right obturator), biopsy:
- One lymph node, negative for metastatic carcinoma (0/1)
5. Lymph node (left external iliac), biopsy:
- One lymph node, negative for metastatic carcinoma (0/1)
6. Lymph node (left obturator), biopsy:
- One lymph node, negative for metastatic carcinoma (0/1)
7. Omentum, partial omentectomy:
- Negative for metastatic carcinoma
8. Uterus, cervix, bilateral fallopian tubes and ovaries, total hysterectomy and bilateral salpingo-oophorectomy:
Endometrium:
- **UTERINE SEROUS CARCINOMA** involving endometrium and endometrial polyp with invasion into polyp stroma
- Background inactive endometrium
Cervix:
- **Cervical stromal involvement by the serous adenocarcinoma**
Myometrium:

[page 2 of 4]
Surgical Pathology Consultation Report

- Not involved by the carcinoma
- Leiomyomata
- Serosa:
- No significant histologic abnormality
- Right ovary:
- No significant histologic abnormality
- Left ovary:
- No significant histologic abnormality
- Bilateral fallopian tubes:
- No significant histologic abnormality

Synoptic Data

Specimen:	Uterine corpus Cervix Right ovary Left ovary Right fallopian tube Left fallopian tube Omentum
Procedure:	Simple hysterectomy Bilateral salpingo-oophorectomy Omentectomy
Lymph Node Sampling:	Performed: Pelvic lymph nodes Performed: Para-aortic lymph nodes
Specimen Integrity:	Intact hysterectomy specimen
Tumor Site:	Other: Both anterior and posterior
Tumor Size:	Greatest dimension: 3.7 cm
Histologic Type:	Serous adenocarcinoma
Histologic Grade:	Not applicable
Myometrial Invasion:	Not identified
Involvement of Cervix:	Invasion of cervical stromal connective tissue
Extent of Involvement of Other Organs:	Right ovary not involved Left ovary not involved Right fallopian tube not involved Left fallopian tube not involved Omentum not involved
Margins:	Uninvolved by invasive carcinoma
Lymph-Vascular Invasion:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2 (II): Tumor invades stromal connective tissue of the cervix, but does not extend beyond uterus
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Pelvic lymph nodes examined: 6 Pelvic lymph nodes involved: 0 Para-aortic lymph nodes examined: 9 Para-aortic lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable

Electronically verified by:

[page 3 of 4]
Surgical Pathology Consultation Report

Gross Description

1. The specimen container labeled with the patient's name and as "right periaortic lymph node", contains a tan fatty lymph node measuring 3.5 x 2.0 x 1.2 cm which is received in 10% neutral buffered formalin. Sectioning reveals a tan fatty cut surface.

1A - 1C - specimen submitted in toto.

2. The specimen container labeled with the patient's name and as "left peri-aortic lymph node", contains two tan fatty lymph nodes measuring 1.0 x 0.8 to 0.6 and 1.6 x 1.0 x 0.5 cm which is received in 10% neutral buffered formalin. Sectioning of both lymph nodes reveals a tan fatty unremarkable cut surface.

2A - single lymph node bisected and submitted in toto.

2B - single lymph node bisected and submitted in toto.

3. The specimen container labeled with the patient's name and as "right external iliac lymph node", contains 3 tan lymph nodes measuring from 1 x 0.7 x 0.6-cm up to 2.0 x 2.0 x 0.7 cm which is received in 10% neutral buffered formalin. Section reveals a tan fatty unremarkable cut surface.

3A - single lymph node serially sectioned.

3B - single lymph node serially sectioned.

3C - single lymph node bisected.

4. The specimen container labeled with the patient's name and as "right obturator", contains a tan fatty lymph node measuring 4 x 1.2 x 0.6 cm which is received in 10% neutral buffered formalin. Sectioning reveals a tan fatty unremarkable cut surface.

4A - 4C - lymph node serially sectioned and submitted in toto.

5. The specimen container labeled with the patient's name and as "left external iliac node", contains a tan fatty lymph node measuring 2.5 x 1.5 x 0.8 cm which is received in 10% neutral buffered formalin. Sectioning reveals a tan fatty unremarkable cut surface.

5A - 5B - lymph node serially sectioned and submitted in toto.

6. The specimen container labeled with the patient's name and as "left obturator", contains a tan fatty lymph node measuring 3.5 x 2.0 x 0.8 cm which is received in 10% neutral buffered formalin. Sectioning reveals a tan fatty unremarkable cut surface.

6A - 6C - lymph node serially sectioned and submitted in toto.

7. The specimen container labeled with the patient's name and as "omentum", contains a fragment of adipose which weighs 77.7 g in the fresh state and measures 15 x 7 x 2.0 cm which is received in 10% neutral buffered formalin. Sectioning the fragment reveals an unremarkable cut surface. No obvious nodules can be grossly identified. No material is taken for ...

7A - 7E - multiple random representative sections.

8. The specimen container labeled with the patient's name and as "uterus cervix bilateral tubes and ovaries", contains a uterine body with attached cervix and bilateral fallopian tubes and ovaries which is received fresh. The specimen weighs 108.1 g in the fresh state. The uterine body measures 7.3 cm SI by 5.0-cm ML by 3.0-cm AP. The exocervix has a diameter of 2.7-cm and appears hemorrhagic. The cervical os is oval with a diameter of 1.1-cm. The left fallopian tube measures 6.5-cm in length to include fimbriated end by 0.4 cm diameter. Sectioning of the tube reveals unremarkable lumen. The left ovary measures 3.3 x 0.6 x 0.5 cm and has an unremarkable external and cut surface. The right fallopian tube measures 5.5-cm in length to include fimbriated end and 0.4 cm in diameter. Sectioning of the tube reveals unremarkable lumen. The right ovary measures 1.8 x 1.3 x 0.5 cm and has an unremarkable external and cut surface. The uterine serosa appears grossly unremarkable. The specimen is bivalved revealing an endocervical canal that measures 2 cm in length by 0.6 cm in width. There is a small polyp identified on the anterior endocervical canal measuring 0.6 cm in length and 0.3 cm in width. The endometrial cavity measures 3.7 cm in length by 2.5 cm from cornu to cornu. This endometrial mass measuring 3.7-cm SI by 3.7-cm ML and occupies the entire anterior endometrial cavity than approximately half of the posterior endometrial cavity. Sectioning through the mass on the posterior wall reveals a mass depth of 1.3-cm and a mass and uterine wall depth of 2.8-cm which represents a greatest depth of invasion of the tumor mass. The mass does not appear to involve the lower uterine segment. There is an intramural fibroid identified on the anterior uterine wall measures 0.4 cm in diameter it has a pale white whorled cut surface. No other obvious abnormalities can be grossly identified. Material is submitted for:

8A - anterior cervix with polyp.

8B - anterior lower uterine segment.

[page 4 of 4]
Surgical Pathology Consultation Report

8C -- posterior cervix.
8D -- posterior lower uterine segment.
8E -- 8F -- full section anterior uterine wall in each block including tumor with resection of fibroid in block 8E.
8G -- 8H -- full section posterior uterine wall with tumor and each block.
8I -- left fimbria of fallopian tube.
8J -- 8 L -- remainder of left fallopian tube submitted in toto.
8M -- 8N -- left ovary submitted in toto.
8O -- right fimbria of fallopian tube.
8P -- 8Q -- remainder of right fallopian tube submitted in toto.
8R -- 8 S -- right ovary submitted in toto.

Source: NCI Genomic Data Commons file 83a5ff13-4581-407a-83ac-b7db826a2919 (TCGA-EO-A3KU.B6945BE4-FA4A-4ED4-9233-B32123F41C95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).